TARGET case TARGET-30-PASSRS — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Other and ill-defined sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2f1a64ad-f106-5c4e-9596-6cf0d22e83ae

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 6 years; Vital status: Dead; Days to death: 1,319 days (3.6 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C76.2; Tissue or organ of origin: Abdomen, NOS; Classification of tumor: primary; Age at diagnosis: 6.8 years (2,492 days); Year of diagnosis: 2009; Days to last follow up: 1,319 days (3.6 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Intermediate.
   Pathology details: Necrosis percent: 15; Percent tumor nuclei: 65.
   Treatment given: Protocol identifier: ADVL0912.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL0532.
   Treatment given: Protocol identifier: ANBL00B1.
   Treatment given: Protocol identifier: ANBL1021.

Follow-up (2 entries)
- Days to follow up: 861 days (2.4 years); Progression or recurrence anatomic site: Bone, NOS; Days to first event: 861 days (2.4 years); First event: Relapse.
- Days to follow up: 1,319 days (3.6 years); Year of follow up: 2012.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PASSRS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PASSRS-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 1319
- Protocol: ANBL00B1, ANBL0532, ANBL0032, ADVL0912, ANBL1021
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.82
- Histology: Unfavorable
- ICDO Description: Abdomen, NOS Abdominal wall, NOS Intra-abdominal site, NOS
- Percent Tumor v/s Stroma: 65/35
- Site of Relapse: Bone
